Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7Z2, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7Z2-01A (Primary Tumor).

[page 1 of 4]
Patient: _____

Surgical Pathology: Additional Info _____

Surg Path

CLINICAL HISTORY:

Brain neoplasm left frontoparietal, left facial seizures. HISTORY OF PRESENT ILLNESS: _____ comes to clinic today. _____. She had a sensory seizure. She had a second sensory seizure. She had two MRI scans that showed a growing lesion in the left frontal area. She is right-handed.

GROSS EXAMINATION:

A. "Brain tissue (Afl)", received fresh for frozen section placed in formalin at _____ is a 0.8 x 0.5 x 0.4 cm aggregate of multiple fragments of soft tan tissue. Representative is frozen as Afl, frozen remnant in A1. Additional sections are submitted in A2, with a small fragment retained in formalin.

B. "Brain tissue", received fresh placed in formalin at _____ is a 1.5 x 1 x 0.5 cm aggregate of multiple fragments of soft tan tissue, submitted in B1 and 2. Small fragments are retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": Afl (representative)-glioma, low grade (Dr. _____)

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a glial neoplasm characterized by cells with round nuclei and delicate chromatin. Satellitosis and minigemistocytes are seen. Mitoses are rare. Endothelial proliferation and necrosis are not seen. The tumor cells are immunopositive for GFAP. HAM56 highlights blood vessels. The Mib-1 index is approximately 15%.

IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the _____

Some of them may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

DIAGNOSIS:

A. BRAIN TISSUE; EXCISION:

OLIGODENDROGLIOMA (WHO GRADE II).

B. BRAIN TISSUE; EXCISION:

OLIGODENDROGLIOMA (WHO GRADE II), WITH ELEVATED MIB-1 INDEX.
SEE COMMENT.

COMMENT: The Mib-1 index is approximately 15% and is worrisome. 1p/19q testing will be performed. Clinical follow-up is indicated.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

*ICD-O 3
Oligodendroglioma, grade II 9450/3
Date 10/15/14
Site ① Brain, supratentorial NOS C71.0
② Brain, overlapping lesions C71.8
7/10 5/15/14*

[page 2 of 4]
Electronically signed: [REDACTED]

ADDENDUM 1:

TISSUE TYPE: BRAIN TISSUE CONTAINING OLIGODENDROGLIOMA WITH ELEVATED MIB-1
INDEX (WHO GRADE II; [REDACTED]).

FISH INTERPRETATION SUMMARY:

FISH MARKER	INTERPRETATION	% OF TUMOR CELLS EXHIBITING ABNORMALITY	FINDINGS/STATUS
EGFR (7p12)	ABNORMAL	93%	GAIN
MET (7q31)	NOT ORDERED		
7 CEP	ABNORMAL	89%	GAIN
PTEN (10q23)	ABNORMAL	82%	LOSS
10 CEP	ABNORMAL	81%	LOSS
1p36	NORMAL		INTACT
1q25	REFERENCE PROBE IS INTACT		
1p32	NORMAL		INTACT
1qtet1	REFERENCE PROBE IS INTACT		
19q13	NORMAL		INTACT
19p13	REFERENCE PROBE IS INTACT		
BRAF (7q34)	NORMAL		INTACT
KIAA1549	NORMAL		INTACT

INTERPRETATION SUMMARY: EGFR, 7 CEP, PTEN, AND 10 CEP: 4 OF 4 ABNORMAL MARKERS.
BRAF:KIAA1549 GENE FUSION/REARRANGEMENT IS NOT EVIDENT. THERE WAS NO EVIDENCE
FOR DELETION OF EITHER CHROMOSOME 1p OR 19q.

COMMENT: SEQUENCING FOR P53 MUTATIONS WILL BE ORDERED REFLEXIVELY AND REPORTED
AS AN ADDENDUM.

Please see Image Cytometry Report [REDACTED] for results of supplementary
tests.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

. M.D.

Electronically signed:

ADDENDUM 2:

358

IHC Antibody:	Interpretation IHC	Score (0-3+)	% of Tumor Cells of Exhibiting Staining	ACIS III SCORE
CD/45-LCA			15%	
Ki-67	HIGH		15% IN SURG PATH	
MGMT	NEGATIVE		10%	11%
EGFR WT	NOT PERFORMED			
EGFR VIII	NOT PERFORMED			
PTEN	NOT PERFORMED			

[page 3 of 4]
I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 4:

Test Performed: TP53 GENE SEQUENCING

Interpretation:
EXTRACTED DNA, [REDACTED] FROM UNSTAINED SLIDES, [REDACTED] (TP53 SEQUENCING FOR LI-FRAUMENI SYNDROME AND SOMATIC MUTATIONS):

NEGATIVE.

TP53 MUTATIONS NOT DETECTED. SEE OBJECTIVE FINDINGS AND COMMENT.

Comment: Mutations in TP53 are rarely found in gliomas with 1p/19q loss of heterozygosity. TP53 mutations are more often found in astrocytic tumors and correlate with a worse prognosis. Additional information can be found in McLendon et al. Cancer. 2005; 104:1693-9 and references within. Clinicians should correlate these results with clinical and other laboratory findings.

The sensitivity of DNA sequencing is 99% for the detection of nucleotide base changes, small deletions, and insertions in the regions analyzed. However, this assay may not detect an acquired mutation which is present below the 25% detection limit (i.e., mutant cell population of < 25%). Only the coding regions of the TP53 gene and immediate flanking intronic sequences were examined. Changes in the promoter region, farther into the introns, or in other non-coding regions of the gene would not be detected. Mutations in genes other than TP53 would not be identified. Large deletions, duplications, multiple exon insertions, sequence alterations adversely affecting primer binding, and complete deletion of one allele may not be identified using these methods. For additional information or for help interpreting the results of this test, please contact the

REFER TO [REDACTED] FOR COMPLETE REPORT AND METHODOLOGY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 5:

Please see MOLECULAR DIAGNOSTICS Report [REDACTED] for complete report.

Testing was performed on sample [REDACTED].

IDH1 MUTATION TESTING WITH REFLEX TO IDH2

INTERPRETATION: NEGATIVE.

IDH1 AND IDH2 MUTATIONS NOT DETECTED.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

[REDACTED] Printed by

[page 4 of 4]
Performed by: SURGICAL PATHOLOGY

Ordering MD:

Source: NCI Genomic Data Commons file 9633f0a4-66ad-4e55-9469-68550d1018f7 (TCGA-E1-A7Z2.2729C641-D25B-4C92-94C8-0BC4C7CE74DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).